Surgical pathology report (de-identified scan), TCGA case TCGA-DH-A66F, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Florida, specimen TCGA-DH-A66F-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Surgicals

Surgical Pathology Consultation / Department of Pathology

ICD-O-3

Oligodendroglioma NOS 9450/3

path Site Brain NOS C71.9

Brain, supratentorial NOS C71.0

W5/10/13

SPECIMEN(S) SUBMITTED / PROCEDURES ORDERED

- | | |
|-------------------|---|
| A. Brain tumor | A. Frozen Section Charge |
| B. Brain tumor | B. 1P19q Malignant Glioma Analysis |
| | B. 1P19q Malignant Glioma Analysis, add |
| | B. Isocitrate dehydrogenase 1 |
| P53 Protein | B. KI-67, Nuclear Antigen, Mib1 |
| Phosphohistone-H3 | B. Glial Fibrill. Acid Prt |

CLINICAL HISTORY: A year old, white male here for left craniotomy for tumor.

DIAGNOSIS:

- A. Brain tumor, biopsy:
Oligodendroglioma, WHO Grade II
- B. Brain tumor, biopsy:
Oligodendroglioma, WHO Grade II, see comment

Comment: Sections reveal an infiltrating neoplasm with largely uniform histology composed of small cells with round nuclei, perinuclear halos, and background chicken-wire like vasculature. Focal calcification and microcystic changes are identified. Although much of the tumor is diffusely infiltrating, a few nodular foci of tumor are appreciated. Extensive search fails to reveal definitive mitoses in this well-sampled material. However, two microfoci of tumor show increased Ki-67 immunolabeling and mitoses are identified by immunohistochemical study for phosphohistone H3 (a marker of mitotic spindles). Immunohistochemical studies reveal strong GFAP reactivity within tumor cell processes. P53 is positive in 10-15% of cell nuclei. Immunohistochemical study for IDH-1 (mutated isocitrate dehydrogenase-1) is strongly and diffusely reactive in the tumor. These findings support an infiltrating oligodendroglioma, which by lack of mitoses on H&E stain would be considered a WHO Grade II tumor. The significance of the microfoci of increased proliferation described above is uncertain.

CHROMOSOMES 1P AND 19Q ANALYSIS:

Fluorescence in situ hybridization (FISH) was performed on representative paraffin-embedded tumor tissue. In this case, deletions of both 1p and 19q were identified.

REFERENCES:

1. CAIRNCROSS JG, ET AL. SPECIFIC GENETIC PREDICTORS OF CHEMOTHERAPEUTIC RESPONSE AND SURVIVAL IN PATIENTS WITH ANAPLASTIC OLIGODENDROGLIOMAS. J NATL CANCER INST 90:1473-1479, 1998.
2. SMITH JS, ET AL. ALTERATIONS OF CHROMOSOME ARMS 1P AND 19Q AS

[page 2 of 2]
PREDICTORS OF SURVIVAL IN OLIGODENDROGLIOMAS, ASTROCYTOMAS, AND MIXED OLIGOASTROCYTOMAS. J CLIN ONCOL 18:636-45, 2000.

3. PERRY A. ANCILLARY FISH ANALYSIS FOR 1P AND 19Q STATUS: PRELIMINARY OBSERVATIONS IN 287 GLIOMAS AND OLIGODENDROGLIOMA MIMICS. FRONT BIOSCI 8:A1-9, 2003.

4. MCDONALD JM, ET AL. THE PROGNOSTIC IMPACT OF HISTOLOGY AND 1P/19Q STATUS IN ANAPLASTIC OLIGODENDROGLIAL TUMORS. CANCER. 104:1468-77, 2005

5. CAIRNCROSS JG. PHASE III TRIAL OF CHEMOTHERAPY PLUS RADIOTHERAPY COMPARED WITH RADIOTHERAPY ALONE FOR PURE AND MIXED ANAPLASTIC OLIGODENDROGLIOMA: INTERGROUP RADIATION THERAPY ONCOLOGY GROUP TRIAL 9402. J CLIN ONCOL. 2006;24:2707-14.

GROSS DESCRIPTION: Received the following specimens in the Department of Pathology, labeled with the patient's name and hospital #

A. Brain tumor

B. Brain tumor

A. The specimen is received fresh, designated "Brain tumor" and consists of multiple irregular and varying size fragments of beige to pink-tan soft tissue measuring 2.5 x 1.5 x 0.5 cm in aggregate. A representative sampling is submitted for touch preparation and frozen section. The resulting intraoperative diagnosis is "Diffuse infiltrating glioma. , " per 1 . Frozen section tissue is

resubmitted for permanent processing in cassette FSA1. The remaining tissue is submitted in cassette A2 with a representative sampling also submitted to the tumor bank. [REDACTED]

B. The specimen is received fresh, designated "Brain tumor" and consists of multiple irregular and varying size fragments of beige to red-tan soft tissue measuring 3.5 x 3.0 x 0.8 cm in aggregate. A representative sampling is submitted to the tumor bank and remaining specimen is submitted entirely in cassettes B1-B3. [REDACTED]

"I, or my qualified designee, performed the gross examination. I have personally reviewed the gross description and performed a microscopic examination on all referenced material. I have personally issued this report on the basis of the gross and microscopic findings."

Note: Test systems have been developed and their performance characteristics determined by [REDACTED] Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

[REDACTED] M.D.

Pathologist

Source: NCI Genomic Data Commons file 2e979d2f-753a-4b00-8a5e-437cb398b9ca (TCGA-DH-A66F.8D9C9718-7904-4C45-8217-D8110552BA51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).